Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0VX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0VX-01A (Primary Tumor).

1CD-0-3

adenocarcinoma, endometroid, NOS 8380/3

Site: Endometrium C54.1

5/1/11

PATIENT HISTORY:

Not provided. LMP: Status post menopause.

PRE-OP DIAGNOSIS: Endometrial cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Total abdominal hysterectomy, bilateral salpingo-oophorectomy.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometroid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Well differentiated (FIGO 1)

ARCHITECTURAL GRADE:

Well differentiated

NUCLEAR GRADE:

Grade 1

TUMOR SIZE:

Maximum dimension: 3.5 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 40 %, Posterior endomyometrium: 40 %

Less than 1/2 thickness of myometrium

DEPTH OF INVASION:**

No

ANGIOLYMPHATIC INVASION:

Complex endometrial hyperplasia with atypia

PRE-NEOPLASTIC CONDITIONS:

(epithelial, smooth muscle, others), Adenomyosis

OTHER:

Total number of lymph nodes examined: 0

LYMPH NODES EXAMINED:

T STAGE, PATHOLOGIC:

pT1b

N STAGE, PATHOLOGIC:

pNX

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IB

Source: NCI Genomic Data Commons file 3cc707de-2fc1-4d54-963c-5b82b9561868 (TCGA-BG-A0VX.D0131F13-2BA5-4B20-8D3D-25743A258C06.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).